CCDI case PBBYPG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/473ce332-a240-4020-a976-02e4264a9d0f

Demographics
Sex at birth: female.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 0.8 years (303 days).

Biospecimens (2 samples)
- Sample 0DL6RG: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DL6RY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
